Somatic mutation profile of tumor specimen TCGA-P5-A733-01A (aliquot TCGA-P5-A733-01A-11D-A32B-08) from TCGA case TCGA-P5-A733, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 52.4 years (19,142 days).
Specimen TCGA-P5-A733-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 100b7b20-41c3-4e59-959a-5593c1f622a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A733-10A (Blood Derived Normal), aliquot TCGA-P5-A733-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97ec7e0e-ddcb-4c14-b8d8-920c07f4b748

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.530C>G p.P177R | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs751477326, CM102507, COSV52661381, COSV52721872, COSV52783879; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV53575279, COSV99570437; called by muse, mutect2
- AHI1 | c.795_798del p.K265Nfs*17 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs754871738; called by pindel, varscan2
- ANO3 | c.1243T>C p.C415R | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.625); catalogued as COSV99884158; called by muse, mutect2, varscan2
- AUTS2 | c.448T>G p.S150A | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100718637; called by muse, mutect2, varscan2
- COL2A1 | c.3003G>A p.S1001= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100477014; called by muse, mutect2
- DNAH12 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.194); catalogued as rs748477425, COSV100244663, COSV60856753; called by muse, mutect2, varscan2
- DNAH7 | c.6296G>A p.R2099Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs373086090; called by muse, mutect2, varscan2
- GGT7 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100322062; called by muse, mutect2, varscan2
- HCK | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99394299; called by muse, mutect2, varscan2
- IDI1 | c.342_344del p.F114del | In Frame Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs754583652; called by pindel, varscan2
- KMT2D | c.4344_4345del p.C1448* | Nonsense Mutation (DEL) | VAF 13/74 reads (18%) | catalogued as rs1064797168; called by pindel, varscan2
- MGAT4A | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53848373; called by muse, varscan2
- MYH11 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1490228863, COSV55542054; ClinVar: uncertain significance; called by muse, mutect2
- MYH7 | c.4187G>A p.R1396Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs370069461; ClinVar: uncertain significance; called by muse, mutect2
- NBPF9 | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 93/249 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV99914331; called by muse, mutect2, varscan2
- NEU2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771380255, COSV52092078; called by muse, mutect2, varscan2
- PABPC4 | c.1744A>G p.M582V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs141368472; called by muse, mutect2, varscan2
- RALGAPB | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV99485493; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1083A>C p.K361N (on ENST00000408927 / NM_001100427.2; = p.K362N on NM_021159.5) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs759363764, COSV99217170; called by muse, mutect2, varscan2
- SEZ6L2 | c.592G>C p.G198R (on ENST00000308713 / NM_001114099.3; = p.G128R on NM_012410.4) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100435638; called by muse, mutect2, varscan2
- SH2D3A | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs896203421, COSV99838123; called by muse, mutect2, varscan2
- STRIP1 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs781349614, COSV100873979; called by muse, varscan2
- TLR7 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 75/141 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs781655586, CM142636, COSV66124444; called by muse, mutect2, varscan2
- TRIM54 | c.14T>G p.V5G | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.63); catalogued as rs781233021, COSV99940609; called by muse, mutect2, varscan2
- VWF | c.4567G>A p.E1523K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.515); catalogued as COSV99779607; called by muse, mutect2, varscan2
- ZNF366 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as rs367714370; called by muse, mutect2, varscan2
- ATRX | c.2912_2915del p.K971Tfs*31 | Frame Shift Del (DEL) | VAF 90/201 reads (45%) | called by pindel, varscan2
- PI4KA | c.6167del p.L2056Pfs*2 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, varscan2
- TRBV4-1 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EP400 | c.8364A>G p.K2788= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100201742; called by muse, mutect2, varscan2
- FOXO4 | c.588C>T p.A196= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100446988; called by muse, mutect2, varscan2
- FOXS1 | c.471G>A p.E157= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99640051; called by muse, mutect2, varscan2
- GREB1 | c.591A>G p.A197= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV52184720; called by muse, mutect2, varscan2
- H3-3A | c.18G>A p.Q6= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100831333, COSV64734750; called by muse, mutect2, varscan2
- KLHDC9 | c.1036C>T p.L346= | Silent (SNP) | VAF 57/135 reads (42%) | catalogued as COSV100919679; called by muse, mutect2, varscan2
- OTUD6A | c.204C>T p.D68= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV57973566; called by muse, mutect2
- TF | c.1929G>A p.S643= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs775523920, COSV99396055, COSV99396149; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.984C>T | RNA (SNP) | VAF 11/82 reads (13%) | catalogued as rs753450394; called by muse, mutect2
